Gene-level copy-number profile of tumor specimen C3L-06649-01 from CPTAC case C3L-06649, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 64.1 years (23,395 days).
Specimen C3L-06649-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bb2ab043-0138-4d7e-8353-94e280f7ed14.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06649-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/aec0478d-bf6f-4308-83d8-7f702eaad298

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 513; copy number 1: 7,240; copy number 2: 40,145; copy number 3: 10,234; copy number 4: 622; copy number 5: 137; copy number 6: 3; copy number 7: 8; copy number 8: 5.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:78,825,281–78,826,006, 1 gene (within-gene range 0–2): RPS3P7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 153 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:113,876,777–115,231,355, 12 genes, copy number 5–8: PPP1R3A, FOXP2, AC073626.2, AC073626.1, AC003992.1, RNA5SP238, MIR3666, MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA.
- chr8:37,983,070–38,468,834, 25 genes, copy number 5: RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22.
- chr17:57,253,236–57,684,689, 2 genes, copy number 5 (within-gene range 2–5): AC091181.2, MSI2.
- chr17:57,448,218–57,834,749, 9 genes, copy number 5–6: AC015883.1, AC007431.2, AC007431.3, AC007431.1, RN7SL449P, RNU7-134P, CCDC182, AC015845.2, RN7SKP94.
- chr17:58,301,228–58,692,055, 17 genes, copy number 5–7 (within-gene range 2–7): TSPOAP1, TSPOAP1-AS1, AC004687.1, MIR142, MIR4736, SUPT4H1, AC004687.2, RNF43, HSF5, SETP3, MTMR4, SEPTIN4-AS1, SEPTIN4, TEX14, U3, IGBP1P2, RNU1-108P.
- chr17:59,859,479–60,666,280, 39 genes, copy number 5: TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P.
- chr17:60,810,165–60,811,462, 1 gene, copy number 5 (within-gene range 3–5): KRT18P61.
- chr20:62,231,922–63,085,071, 48 genes, copy number 5: OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659, MRGBP, OGFR-AS1, OGFR, COL9A3, TCFL5, DPH3P1, ARF4P2, DIDO1, AL117379.1, GID8, SLC17A9, BHLHE23, LINC01749, LINC00029, LINC01056.

Autosomal genes at a single copy (total copy number 1): 5,934. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
